Somatic mutation profile of tumor specimen TCGA-56-8624-01A (aliquot TCGA-56-8624-01A-11D-2395-08) from TCGA case TCGA-56-8624, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 84.3 years (30,798 days).
Specimen TCGA-56-8624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 695f8c38-f408-45f5-8c12-973acdac0f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8624-10A (Blood Derived Normal), aliquot TCGA-56-8624-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a12b53e-f8de-4723-8ace-b768969830f7

The open-access MAF lists 124 somatic variants for this specimen: 93 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 28, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 3'UTR 1, RNA 1, Intron 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1216-1G>C p.X406_splice | Splice Site (SNP) | VAF 36/102 reads (35%) | hotspot (GDC flag); catalogued as CS971888, COSV57295479, COSV57298451, COSV57332521; called by muse, mutect2, varscan2
- ABCA9 | c.2480C>G p.S827C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100382634; called by muse, mutect2, varscan2
- AKAP17A | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100001881; called by muse, mutect2, varscan2
- ARF1 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99683046; called by muse, mutect2, varscan2
- ATL2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100184418; called by muse, mutect2, varscan2
- ATP1A2 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV100767636; called by muse, mutect2, varscan2
- CACNG8 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99554861; called by muse, mutect2, varscan2
- CAMK4 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99998332; called by muse, mutect2, varscan2
- CCL8 | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs368550510, COSV67013919; called by muse, mutect2, varscan2
- CNTNAP3 | c.3265G>A p.D1089N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99904126; called by muse, mutect2, varscan2
- CNTNAP4 | c.2639G>T p.R880M | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV56698975; called by muse, mutect2, varscan2
- COCH | c.1263G>C p.M421I (on ENST00000216361 / NM_001347720.1; = p.M356I on NM_004086.3) | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV99363384; called by muse, mutect2, varscan2
- CYTH4 | c.432C>T p.L144= | Splice Region (SNP) | VAF 12/53 reads (23%) | catalogued as COSV50632796; called by muse, mutect2, varscan2
- DPP8 | c.580C>T p.P194S (on ENST00000341861 / NM_001320875.2; = p.P178S on NM_017743.6) | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV100202110; called by muse, mutect2, varscan2
- EDIL3 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.425); catalogued as COSV56926507, COSV99674803; called by muse, mutect2
- EGFLAM | c.2712-1G>T p.X904_splice (on ENST00000354891 / NM_001205301.2; = p.X896_splice on NM_152403.4) | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100379834; called by muse, mutect2, varscan2
- ELAPOR2 | c.985G>T p.D329Y (on ENST00000450689 / NM_001142749.3; = p.D162Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV51886717, COSV99788207; called by muse, mutect2, varscan2
- ELAVL4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs763739803, COSV100836563; called by mutect2, varscan2
- ELAVL4 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs761620230, COSV100836565; called by mutect2, varscan2
- ELOA2 | c.1208C>G p.A403G | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99795946; called by muse, mutect2, varscan2
- ESPL1 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 45/336 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.185); catalogued as COSV57759129, COSV99228919; called by muse, mutect2, varscan2
- FAM90A1 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV100274186; called by muse, mutect2, varscan2
- FBLIM1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.766); catalogued as COSV60028855; called by muse, mutect2, varscan2
- FSTL5 | c.2077G>T p.V693L | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.285); catalogued as COSV100052878; called by muse, mutect2, varscan2
- GABRB2 | c.1006del p.Q336Nfs*71 (on ENST00000274547; = p.Q336Nfs*33 on NM_000813.3) | Frame Shift Del (DEL) | VAF 26/154 reads (17%) | catalogued as COSV99196735; called by mutect2, pindel, varscan2
- GIMAP5 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500213; called by muse, mutect2, varscan2
- GLG1 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs1214461271, COSV99215287, COSV99215501; called by muse, mutect2, varscan2
- HECW1 | c.3830G>A p.R1277Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs150833111, COSV67833322; called by muse, mutect2, varscan2
- IFT57 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as COSV99197239; called by muse, mutect2
- IGSF1 | c.3532G>T p.D1178Y | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63837976; called by muse, mutect2, varscan2
- IL4R | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99404715; called by muse, mutect2, varscan2
- KIF1A | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs376697478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP10-3 | c.665G>C p.*222Sext*15 | Nonstop Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100551944; called by muse, mutect2, varscan2
- LHX9 | c.906G>C p.Q302H | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100435623; called by muse, mutect2
- MACF1 | c.5157G>A p.M1719I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV99241338; called by muse, mutect2, varscan2
- MFRP | c.155G>C p.C52S (on ENST00000449574; = p.C428S on NM_031433.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100793345; called by muse, mutect2, varscan2
- MYOC | c.1309T>A p.Y437N | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM971025, COSV99231308; called by muse, mutect2, varscan2
- NBEAL2 | c.4604G>T p.C1535F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99434540; called by muse, mutect2, varscan2
- NOD1 | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99767794; called by muse, mutect2
- NOX5 | c.1432T>A p.Y478N | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99533330; called by muse, mutect2, varscan2
- NPC1L1 | c.2732C>T p.S911F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1299519630, COSV56928973; called by muse, mutect2, varscan2
- NPHS1 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201750873, COSV100799611, COSV62287075; called by muse, mutect2, varscan2
- NRXN3 | c.1835G>A p.R612H (on ENST00000335750 / NM_001330195.2; = p.R239H on NM_004796.6) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59744136; called by muse, mutect2, varscan2
- OR4E2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.119); catalogued as COSV100330018; called by muse, mutect2, varscan2
- OR5H15 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100736613, COSV62947918; called by muse, mutect2, varscan2
- OR5I1 | c.50T>G p.L17* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100041216; called by muse, mutect2, varscan2
- OSER1 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99667276; called by muse, mutect2, varscan2
- PAX3 | c.989G>T p.R330I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100398963, COSV100399048; called by muse, mutect2, varscan2
- PCDHA13 | c.1142C>G p.S381* | Nonsense Mutation (SNP) | VAF 17/217 reads (8%) | catalogued as COSV99165051; called by muse, mutect2
- PCDHAC1 | c.1751T>A p.V584E | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99165052; called by muse, mutect2, varscan2
- PCDHB12 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.078); catalogued as COSV99506756; called by muse, mutect2, varscan2
- PCDHB8 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV99175726; called by muse, mutect2
- PCDHGA2 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1310037589, COSV54021897; called by muse, mutect2, varscan2
- PDSS2 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100941622; called by muse, mutect2, varscan2
- POLB | c.777G>T p.L259F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.165); catalogued as COSV99612520; called by muse, mutect2, varscan2
- PSKH2 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99404983, COSV99405375; called by muse, mutect2, varscan2
- PSPC1 | c.1311G>T p.M437I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100142162, COSV58887469; called by muse, mutect2, varscan2
- PTPRB | c.2913G>T p.Q971H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.617); catalogued as COSV99715895; called by muse, mutect2, varscan2
- PTPRC | c.1203A>T p.R401S | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100722126; called by muse, mutect2, varscan2
- QPCT | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621515; called by muse, mutect2, varscan2
- QPCT | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621517; called by muse, mutect2, varscan2
- RELN | c.4690C>G p.L1564V | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100632525; called by muse, mutect2, varscan2
- RIMS1 | c.3277G>T p.V1093L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99324273; called by muse, mutect2, varscan2
- RING1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs775970204, COSV100761721; called by muse, mutect2, varscan2
- RNF103 | c.2054C>G p.S685C | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV99409936; called by muse, mutect2, varscan2
- RPL13 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99244582; called by muse, mutect2
- SCN9A | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs1210104999, COSV100311451; called by muse, mutect2, varscan2
- SHTN1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760926506, COSV53379930; called by mutect2, varscan2
- SLU7 | c.882G>C p.E294D | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99775449; called by muse, mutect2, varscan2
- SORCS1 | c.2231C>A p.P744Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755492792, COSV99543471; called by muse, mutect2, varscan2
- SPAG17 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.96); catalogued as COSV60468426; called by muse, mutect2, varscan2
- STAB2 | c.1369T>A p.L457M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101185633; called by muse, mutect2, varscan2
- STIMATE | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100753616; called by muse, mutect2, varscan2
- SYNE1 | c.2123G>A p.R708K (on ENST00000367255 / NM_182961.4; = p.R715K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55066161; called by muse, mutect2, varscan2
- TBC1D26 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1273518189, COSV101343643; called by muse, mutect2, varscan2
- TLN2 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV100168031; called by muse, mutect2, varscan2
- TNXB | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100925872; called by muse, mutect2, varscan2
- TP53 | c.801del p.N268Tfs*77 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as COSV52712702, COSV53164528, COSV53387047; called by mutect2, pindel, varscan2
- TP53BP2 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV100636506; called by muse, varscan2
- TP53BP2 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100636507; called by muse, varscan2
- TSHR | c.2096G>A p.C699Y | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV99991070, COSV99991526; called by muse, mutect2, varscan2
- TSNARE1 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs367607963, COSV100209876; called by muse, mutect2
- TTBK1 | c.3154C>A p.P1052T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.036); catalogued as COSV99443761; called by muse, mutect2, varscan2
- UBQLN1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs201974454; called by muse, mutect2, varscan2
- UIMC1 | c.914A>G p.K305R | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101022036; called by muse, mutect2, varscan2
- VWF | c.8185G>T p.A2729S | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as COSV99778039; called by muse, mutect2, varscan2
- ZHX3 | c.418T>C p.W140R | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100475482; called by muse, mutect2, varscan2
- ZNF274 | c.763G>A p.E255K (on ENST00000610905; = p.E150K on NM_016324.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as rs929894746, COSV100464713; called by muse, mutect2
- ZNF600 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs1306753725, COSV100592904; called by muse, mutect2
- ZNF804A | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100166487; called by muse, mutect2, varscan2
- ZNF804B | c.3098T>C p.L1033P | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV60822513; called by muse, mutect2, varscan2
- ZNF92 | c.760G>A p.E254K (on ENST00000328747 / NM_152626.4; = p.E185K on NM_007139.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV100165669, COSV60873032; called by muse, mutect2, varscan2
- ABCB1 | c.1923del p.D642Mfs*21 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- ABHD16A | c.48C>T p.I16= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101012175; called by muse, mutect2
- ADAM21 | c.1143T>A p.A381= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV99960516; called by muse, mutect2, varscan2
- ARHGAP10 | c.18G>A p.L6= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1560728682, COSV100330909; called by muse, mutect2, varscan2
- ARHGEF18 | c.1512C>T p.N504= (on ENST00000359920 / NM_001130955.2; = p.N400= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs775761605, COSV60470599; called by muse, mutect2, varscan2
- CACNA2D4 | c.405G>C p.R135= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV99765059; called by muse, mutect2
- CFAP100 | c.1000C>A p.R334= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV61502548, COSV61503687; called by muse, mutect2, varscan2
- CILP | c.1131G>A p.K377= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99972826; called by muse, mutect2
- CPNE3 | c.1266G>A p.V422= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as COSV99547176; called by muse, mutect2, varscan2
- DNAH5 | c.5469A>G p.S1823= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99445282; called by mutect2, varscan2
- FAM90A1 | c.915C>A p.P305= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100274185; called by muse, mutect2, varscan2
- GOLGB1 | c.5898T>C p.S1966= | Silent (SNP) | VAF 26/280 reads (9%) | catalogued as COSV100510351; called by muse, mutect2
- HSPA12A | c.1911C>T p.P637= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs781805969, COSV65022456; called by muse, mutect2, varscan2
- HTR2C | c.180C>A p.I60= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV52224285, COSV99348159; called by muse, mutect2, varscan2
- MEIOC | c.1293C>T p.P431= | Silent (SNP) | VAF 43/129 reads (33%) | catalogued as rs367775822; called by muse, mutect2, varscan2
- MYH8 | c.4068C>A p.G1356= | Silent (SNP) | VAF 33/161 reads (20%) | catalogued as COSV101238202; called by muse, mutect2, varscan2
- NME4 | c.156G>T p.R52= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99556705; called by muse, mutect2, varscan2
- NPHP3 | c.1233G>A p.L411= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV100446617; called by muse, mutect2, varscan2
- PCDHA12 | c.720G>A p.P240= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs782181168, COSV100247692; called by muse, mutect2, varscan2
- PRSS55 | c.318G>T p.A106= | Silent (SNP) | VAF 64/309 reads (21%) | catalogued as COSV100153625; called by muse, mutect2, varscan2
- RASGEF1C | c.960G>T p.V320= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV100745611; called by muse, mutect2, varscan2
- SLC6A5 | c.1266G>T p.V422= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100116454; called by muse, varscan2
- SMU1 | c.75G>T p.R25= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV101238498; called by muse, mutect2, varscan2
- SULT1C3 | c.255T>C p.D85= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100227320; called by muse, mutect2
- TLR7 | c.2175C>G p.L725= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV101027720; called by muse, mutect2, varscan2
- TRIM2 | c.42C>G p.R14= (on ENST00000437508; = p.R41= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV100107574; called by muse, mutect2, varscan2
- UGT8 | c.1011C>G p.L337= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100178978; called by muse, mutect2
- VWF | c.8184T>C p.T2728= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99778040; called by muse, mutect2, varscan2
- ZNF324B | c.585G>A p.Q195= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100351525; called by muse, mutect2, varscan2
- FOLH1B | n.1734C>T | RNA (SNP) | VAF 6/80 reads (8%) | catalogued as rs1405183967; called by muse, mutect2
- MEIS3 | c.859-103C>A | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100520358; called by muse, varscan2
- SLIT3 | c.*2C>T | 3'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs1009814278, COSV100265491; called by mutect2, varscan2
